Somatic mutation profile of tumor specimen MP2PRT-PARHLX-TMP1-A (aliquot MP2PRT-PARHLX-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARHLX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (579 days).
Specimen MP2PRT-PARHLX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 415da706-f3e7-43f2-a3eb-15537b388ade.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARHLX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARHLX-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/462b7028-7b46-49fa-ab43-8af4897ee3f8

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EEF2 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 70/708 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58579201; called by muse, mutect2
- COL6A3 | c.9211C>T p.H3071Y | Missense Mutation (SNP) | VAF 151/281 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OCSTAMP | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 79/324 reads (24%) | called by muse, mutect2, varscan2
- SI | c.1518G>T p.M506I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- DRC7 | c.2328C>T p.C776= | Silent (SNP) | VAF 26/536 reads (5%) | called by muse, mutect2
